Somatic mutation profile of tumor specimen TCGA-VG-A8LO-01A (aliquot TCGA-VG-A8LO-01A-11D-A403-09) from TCGA case TCGA-VG-A8LO, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GB; Age at diagnosis: 55.5 years (20,274 days).
Specimen TCGA-VG-A8LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 412086a9-3810-4938-9497-c7d99c3174c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VG-A8LO-10A (Blood Derived Normal), aliquot TCGA-VG-A8LO-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1e7c4a4-2083-42b2-819c-82eedbd79951

The open-access MAF lists 75 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 13, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNG | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as rs1559302834, COSV99285625; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 16/17 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2689A>G p.T897A | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV99709979; called by muse, mutect2, varscan2
- ABHD11 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99766747; called by muse, mutect2, varscan2
- ADGRL3 | c.503T>G p.V168G (on ENST00000506720 / NM_001322402.2; = p.V100G on NM_015236.6) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV101546952; called by muse, mutect2, varscan2
- ALAS1 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050255; called by muse, mutect2, varscan2
- ARHGAP32 | c.5796A>T p.Q1932H (on ENST00000310343 / NM_001378025.1; = p.Q1583H on NM_014715.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100087333; called by muse, mutect2, varscan2
- ASTN2 | c.3201G>T p.Q1067H (on ENST00000313400 / NM_001365069.1; = p.Q1016H on NM_014010.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.36); catalogued as COSV99940485; called by muse, mutect2, varscan2
- ATP6V1A | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 105/174 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849976; called by muse, mutect2, varscan2
- BRINP3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs144952455, COSV66521744; called by muse, mutect2, varscan2
- BTF3 | c.305G>C p.G102A (on ENST00000380591 / NM_001037637.1; = p.G58A on NM_001207.4) | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.819); catalogued as COSV100246658; called by muse, mutect2
- C3 | c.3288C>A p.D1096E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99836345; called by muse, mutect2, varscan2
- CA3 | c.237del p.R80Efs*55 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as COSV53410633; called by mutect2, pindel*, varscan2
- CCDC71 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100422325; called by muse, varscan2
- CDAN1 | c.2896G>A p.V966M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV62333767; called by muse, mutect2, varscan2
- CEP68 | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99560745; called by muse, mutect2, varscan2
- COL6A3 | c.6671A>C p.Q2224P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs754395952, COSV99797055; called by muse, mutect2
- CREB3L3 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99314005; called by muse, mutect2, varscan2
- DROSHA | c.1630C>G p.R544G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100757542; called by muse, mutect2, varscan2
- DSCAML1 | c.6254A>T p.D2085V (on ENST00000321322; = p.D2025V on NM_020693.4) | Missense Mutation (SNP) | VAF 89/133 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV100355329; called by muse, mutect2, varscan2
- DSN1 | c.370A>C p.I124L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101040991; called by muse, mutect2, varscan2
- FAAH | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV99679989; called by muse, mutect2, varscan2
- FGF8 | c.527G>A p.R176Q (on ENST00000344255 / NM_033164.4; = p.R158Q on NM_006119.6) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs138208879; called by muse, mutect2, varscan2
- GALNT15 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100327448; called by muse, mutect2, varscan2
- GFRA4 | c.786C>A p.N262K (on ENST00000319242 / NM_145762.3; = p.N232K on NM_022139.4) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99293862; called by muse, mutect2
- HCN2 | c.1550G>A p.S517N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99241496; called by muse, mutect2
- HOXA3 | c.712T>A p.W238R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415371; called by muse, mutect2, varscan2
- HRH1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs200571067; called by muse, varscan2
- HYAL4 | c.1006A>T p.I336F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99772137; called by muse, mutect2
- LGR6 | c.1582G>C p.D528H (on ENST00000367278 / NM_001017403.1; = p.D476H on NM_021636.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99706463; called by muse, mutect2, varscan2
- MAEL | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100901752; called by muse, mutect2, varscan2
- MGAT5B | c.1849-1G>T p.X617_splice (on ENST00000569840 / NM_001199172.2; = p.X615_splice on NM_144677.3) | Splice Site (SNP) | VAF 50/51 reads (98%) | catalogued as COSV100047627; called by muse, mutect2, varscan2
- MON2 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99742059; called by muse, mutect2, varscan2
- MUC6 | c.7094C>T p.A2365V | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs770478474, COSV100172671; called by muse, mutect2, varscan2
- MYH1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as rs1349456975, COSV56850403, COSV99875292; called by muse, mutect2, varscan2
- MYO7A | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1366009175, COSV68684908; called by muse, mutect2, varscan2
- NEB | c.7861G>A p.D2621N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.706); catalogued as rs781745506, COSV99418244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NME9 | c.736C>T p.R246* (on ENST00000333911 / NM_001349024.2; = p.R185* on NM_178130.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/26 reads (88%) | catalogued as rs764938575, COSV100444639; called by muse, mutect2, varscan2
- OR13G1 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100687141, COSV62943844; called by muse, mutect2
- PCDH9 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100119416; called by muse, mutect2, varscan2
- POGZ | c.65G>C p.S22T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as COSV55038081, COSV99652537; called by muse, mutect2, varscan2
- PRDM12 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV53392001, COSV99446147; called by muse, mutect2, varscan2
- PRKCG | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99668752, COSV99669372; called by muse, mutect2, varscan2
- RAI14 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as rs755270189, COSV99462443; called by muse, mutect2, varscan2
- SHQ1 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148030588, COSV100344762; called by muse, mutect2, varscan2
- TARS3 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1009609339, COSV100254436; called by muse, mutect2, varscan2
- TBCB | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99387469; called by muse, mutect2, varscan2
- TBX21 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1032967567, COSV99455922; called by muse, mutect2, varscan2
- TM4SF4 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs748715174, COSV100541821; called by muse, mutect2, varscan2
- TMEM156 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1392744075, COSV100756033; called by muse, mutect2, varscan2
- TRIP11 | c.5233G>C p.E1745Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV99970469; called by muse, mutect2, varscan2
- TRPM2 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100308444; called by muse, mutect2, varscan2
- UBE2T | c.552T>G p.S184R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100937910; called by muse, mutect2, varscan2
- UBQLN2 | c.305T>A p.I102N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100592665; called by muse, mutect2, varscan2
- VNN3 | c.504T>G p.D168E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs372135279; called by muse, mutect2, varscan2
- ZNF83 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56530086; called by muse, mutect2, varscan2
- CHERP | c.877-1_889del p.X293_splice | Splice Site (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- KLRK1 | c.356del p.N119Tfs*17 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- PDZD7 | c.1480_1485del p.G494_S495del | In Frame Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- RESF1 | c.1142_1146del p.N381Sfs*16 | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | called by mutect2, pindel, varscan2
- TPTE | c.1590T>A p.D530E (on ENST00000618007 / NM_199261.4; = p.D512E on NM_199259.4) | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CHD2 | c.3897G>A p.V1299= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV101244934; called by muse, mutect2, varscan2
- COL17A1 | c.2808T>A p.G936= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- CUEDC2 | c.36T>A p.L12= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99827811; called by muse, mutect2, varscan2
- DDX23 | c.1836G>A p.A612= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs779423609, COSV99974779; called by muse, mutect2, varscan2
- DOCK4 | c.5568G>A p.R1856= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV101447809; called by muse, mutect2, varscan2
- GARRE1 | c.2994C>G p.L998= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as rs779572479, COSV100209117, COSV100209209; called by muse, mutect2, varscan2
- LZTS3 | c.1095C>G p.A365= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs781279351, COSV100232207; called by muse, varscan2
- MYLK3 | c.105G>A p.K35= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as rs1403593316, COSV101189082; called by muse, mutect2, varscan2
- NCOA2 | c.714C>T p.I238= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV101475921; called by muse, mutect2, varscan2
- PDS5A | c.2988G>T p.L996= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as COSV100337250; called by muse, mutect2, varscan2
- PLXNA4 | c.2319G>A p.E773= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100323338; called by muse, mutect2, varscan2
- TMCC2 | c.1950C>T p.I650= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs371544078, COSV100319229; called by muse, mutect2, varscan2
- TRIM67 | c.1950G>A p.V650= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100792076; called by muse, mutect2, varscan2
- MACF1 | c.15832-10583A>C | Intron (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99242732; called by muse, mutect2, varscan2
